Gene-level copy-number profile of tumor specimen ALCH-B487-TTP1-A from ALCHEMIST case ALCH-B487, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 55.2 years (20,176 days).
Specimen ALCH-B487-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7c6c484d-7679-4030-b1b5-d4163d918be5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B487-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,748 have no estimate.
https://portal.gdc.cancer.gov/files/88505c2e-0829-406a-be06-c694c609c637

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 62; copy number 1: 13,491; copy number 2: 44,883; copy number 3: 295; copy number 4: 50; copy number 5: 53; copy number 7: 20; copy number 8: 10; copy number 9: 1; copy number 12: 10.

Homozygous deletions (total copy number 0; autosomes only): 46 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:132,003,592–132,080,133, 5 genes (within-gene range 0–1): ACSL6-AS1, AC034228.1, IL3, CSF2, AC034216.1.
- chr5:135,038,831–135,040,047, 1 gene (within-gene range 0–1): C5orf66-AS1.
- chr10:69,801,880–69,964,275, 1 gene: COL13A1.
- chr11:45,647,689–45,665,622, 2 genes: CHST1, AC087442.1.
- chr11:45,921,621–45,929,096, 1 gene: LARGE2.
- chr11:70,862,790–70,872,368, 2 genes (within-gene range 0–1): SHANK2-AS3, MIR3664.
- chr11:71,527,267–71,568,934, 6 genes (within-gene range 0–1): KRTAP5-7, KRTAP5-8, KRTAP5-9, AP000867.5, KRTAP5-10, AP000867.1.
- chr11:72,708,186–72,708,565, 1 gene (within-gene range 0–1): RPS12P20.
- chr15:25,169,337–25,178,819, 6 genes (within-gene range 0–2): DMAC1P1, SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5.
- chr15:25,187,536–25,189,495, 2 genes (within-gene range 0–2): SNORD115-10, SNORD115-11.
- chr15:25,211,796–25,211,877, 1 gene (within-gene range 0–2): SNORD115-23.
- chr15:25,222,348–25,250,940, 17 genes (within-gene range 0–2): SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr17:76,376,584–76,387,860, 1 gene (within-gene range 0–2): SPHK1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 94 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:96,828,669–96,828,764, 1 gene, copy number 9: MIR607.
- chr18:721,588–812,546, 1 gene, copy number 12 (within-gene range 4–12): YES1.
- chr18:797,989–5,895,955, 92 genes, copy number 5–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10,743. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
